Somatic mutation profile of tumor specimen TCGA-FV-A3I1-01A (aliquot TCGA-FV-A3I1-01A-11D-A22F-10) from TCGA case TCGA-FV-A3I1, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2.
Specimen TCGA-FV-A3I1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91512e3f-4731-4b3b-84c4-8fe05b4b40ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FV-A3I1-10A (Blood Derived Normal), aliquot TCGA-FV-A3I1-10A-01D-A22F-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a54bbb55-2f72-4e81-9f4f-699e1e7965b0

The open-access MAF lists 84 somatic variants for this specimen: 61 protein-altering or splice-affecting, 19 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 19, Frame Shift Ins 2, Splice Site 2, 3'UTR 2, Splice Region 2, Nonsense Mutation 2, Frame Shift Del 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 31/65 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGB | c.4537+1G>A p.X1513_splice | Splice Site (SNP) | VAF 22/53 reads (42%) | catalogued as rs370591540; called by muse, mutect2, varscan2
- ANKHD1 | c.7227A>T p.S2409= | Splice Region (SNP) | VAF 35/126 reads (28%) | catalogued as COSV51848273; called by muse, mutect2, varscan2
- APAF1 | c.1357C>A p.L453I (on ENST00000551964 / NM_181861.2; = p.L442I on NM_001160.3) | Missense Mutation (SNP) | VAF 60/176 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.205); catalogued as COSV59664471; called by muse, varscan2
- BBX | c.2345C>T p.P782L (on ENST00000325805 / NM_001142568.3; = p.P752L on NM_020235.7) | Missense Mutation (SNP) | VAF 56/233 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.072); catalogued as COSV57885486; called by muse, mutect2, varscan2
- C9orf64 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs1255636282, COSV59032619; called by muse, mutect2, varscan2
- CACNG7 | c.209G>T p.G70V | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV55813125, COSV55814330; called by muse, mutect2, varscan2
- DEPDC1 | c.2065_2068del p.L689Rfs*11 (on ENST00000456315 / NM_001114120.3; = p.L405Rfs*11 on NM_017779.6) | Frame Shift Del (DEL) | VAF 50/168 reads (30%) | catalogued as rs760374659; called by pindel, varscan2
- DNAH10 | c.12353T>C p.M4118T (on ENST00000409039; = p.M4057T on NM_207437.3) | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV68994667; called by muse, mutect2, varscan2
- DPYD | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64599007; called by muse, mutect2, varscan2
- EDIL3 | c.67G>A p.G23S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as rs776762718, COSV56900210; called by muse, mutect2, varscan2
- EPHA1 | c.1073C>A p.T358K | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.142); catalogued as COSV51971846; called by muse, mutect2
- EPHA1 | c.1071T>A p.D357E | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as COSV51971858; called by muse, mutect2
- EXOSC3 | c.47G>A p.R16K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV100520439, COSV59203831; called by muse, mutect2, varscan2
- EYS | c.1657C>A p.L553I | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as COSV60987172; called by muse, mutect2, varscan2
- FAM184A | c.324T>G p.I108M | Missense Mutation (SNP) | VAF 72/226 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.917); catalogued as COSV58854829; called by muse, mutect2, varscan2
- FAM47A | c.872C>G p.T291R | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.702); catalogued as COSV60497134, COSV60497876; called by muse, mutect2, varscan2
- GSDME | c.520A>G p.M174V | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761265129, COSV61651822; called by muse, mutect2, varscan2
- HDC | c.1456C>T p.R486W | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs778709808, COSV51071127; called by muse, mutect2, varscan2
- HSPA5 | c.667T>G p.F223V | Missense Mutation (SNP) | VAF 47/87 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV61029275; called by muse, mutect2, varscan2
- ITGB3BP | c.6-2A>G p.X2_splice | Splice Site (SNP) | VAF 96/302 reads (32%) | catalogued as rs969231213, COSV52133043; called by muse, mutect2, varscan2
- KAT5 | c.822G>T p.K274N | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.18); catalogued as COSV57729772; called by muse, mutect2, varscan2
- KIF20B | c.4873A>G p.I1625V (on ENST00000371728 / NM_001284259.2; = p.I1585V on NM_016195.4) | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53308282; called by muse, mutect2, varscan2
- L1CAM | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 69/211 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs202000092, COSV62828302; called by muse, mutect2, varscan2
- LDB1 | c.257A>G p.D86G (on ENST00000425280 / NM_001321612.2; = p.D50G on NM_003893.5) | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV63289135; called by muse, mutect2, varscan2
- LHB | c.179C>A p.T60N | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55485467; called by muse, mutect2, varscan2
- MAOB | c.724A>T p.R242* | Nonsense Mutation (SNP) | VAF 44/113 reads (39%) | catalogued as COSV65205456; called by muse, mutect2, varscan2
- MAP3K4 | c.1220T>G p.L407* | Nonsense Mutation (SNP) | VAF 64/168 reads (38%) | catalogued as COSV62334257; called by muse, mutect2, varscan2
- MRGPRE | c.684C>A p.F228L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (1); PolyPhen possibly damaging (0.47); catalogued as COSV67745734; called by muse, mutect2, varscan2
- MRPS15 | c.398C>G p.S133C | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs376585999; called by muse, mutect2, varscan2
- MXRA5 | c.8318C>T p.S2773L | Missense Mutation (SNP) | VAF 73/232 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.695); catalogued as rs1366305934, COSV54237231; called by muse, mutect2, varscan2
- MYO3A | c.1945G>T p.A649S | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV56333040; called by muse, mutect2, varscan2
- MYOT | c.860G>T p.G287V | Missense Mutation (SNP) | VAF 54/181 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53514978; called by muse, mutect2, varscan2
- NEURL4 | c.823G>C p.V275L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.122); catalogued as COSV59759427; called by muse, mutect2, varscan2
- NLGN1 | c.1913C>A p.P638H | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV64335135, COSV99053729; called by muse, mutect2, varscan2
- NOP56 | c.434A>G p.Q145R | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV61390193; called by muse, mutect2, varscan2
- OCLN | c.421A>T p.M141L | Missense Mutation (SNP) | VAF 111/313 reads (35%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV62285438; called by muse, mutect2, varscan2
- ODC1 | c.1213A>G p.I405V | Missense Mutation (SNP) | VAF 96/137 reads (70%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV52172425; called by muse, mutect2, varscan2
- PALM3 | c.336G>T p.R112S (on ENST00000340790; = p.R127S on NM_001145028.2) | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs998902486, COSV54601105; called by muse, mutect2, varscan2
- PHF2 | c.709T>G p.C237G | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63681242; called by muse, mutect2, varscan2
- PIN4 | c.353C>A p.P118Q (on ENST00000664196; = p.P93Q on NM_006223.4) | Missense Mutation (SNP) | VAF 93/300 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.844); catalogued as rs1423088655, COSV54485019; called by muse, mutect2, varscan2
- PLCL1 | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 112/153 reads (73%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1236965488, COSV101407246; called by muse, mutect2, varscan2
- PPEF2 | c.1506G>T p.K502N | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747832342, COSV54422810, COSV54426183; called by muse, mutect2, varscan2
- RAB6A | c.133A>G p.T45A | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV60178525; called by muse, mutect2, varscan2
- RP1 | c.3464A>G p.N1155S | Missense Mutation (SNP) | VAF 59/242 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV55118011; called by muse, mutect2, varscan2
- RTL8B | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.156); catalogued as COSV66954314; called by muse, mutect2, varscan2
- SETD2 | c.6353C>T p.T2118I | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57438981; called by muse, mutect2, varscan2
- SPTBN5 | c.6825G>A p.E2275= | Splice Region (SNP) | VAF 20/68 reads (29%) | catalogued as COSV58021523; called by muse, mutect2, varscan2
- TENM3 | c.3280T>C p.W1094R | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV69309582; called by muse, mutect2, varscan2
- TFAP2A | c.1220C>A p.A407D (on ENST00000482890; = p.A399D on NM_001032280.3) | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60234045; called by muse, mutect2, varscan2
- THSD7B | c.160G>C p.G54R | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55692381; called by muse, mutect2, varscan2
- TNFRSF1A | c.95C>A p.P32H | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV50828561; called by muse, mutect2, varscan2
- WDR36 | c.2156C>A p.T719N | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs748204022, COSV72605230; called by muse, mutect2, varscan2
- ZBTB9 | c.1233T>A p.F411L | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV67702116; called by muse, mutect2
- ZFX | c.2303C>A p.S768Y | Missense Mutation (SNP) | VAF 109/303 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58447225, COSV58447776; called by muse, mutect2, varscan2
- ZNF354B | c.929G>C p.R310T | Missense Mutation (SNP) | VAF 63/201 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.048); catalogued as COSV59366365; called by muse, mutect2, varscan2
- ZNF559 | c.1248A>C p.K416N | Missense Mutation (SNP) | VAF 45/84 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57835738; called by muse, mutect2, varscan2
- CEP350 | c.7376_7377insT p.K2459Nfs*5 | Frame Shift Ins (INS) | VAF 141/353 reads (40%) | called by mutect2, pindel, varscan2
- CYP4A22 | c.688dup p.C230Lfs*9 | Frame Shift Ins (INS) | VAF 45/164 reads (27%) | called by mutect2, pindel, varscan2
- KMT2D | c.11069G>T p.G3690V | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- KMT2D | c.11068G>A p.G3690R | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3924T>C p.C1308= | Silent (SNP) | VAF 57/162 reads (35%) | catalogued as COSV51848249; called by muse, mutect2, varscan2
- APBA2 | c.1860C>T p.S620= | Silent (SNP) | VAF 38/119 reads (32%) | catalogued as COSV67104865; called by muse, mutect2, varscan2
- CDHR1 | c.1542T>A p.T514= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as rs779290074, COSV60562899; called by muse, mutect2, varscan2
- COPG1 | c.393C>A p.I131= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs1416895782, COSV59114372, COSV59114382; called by muse, mutect2, varscan2
- DNAH12 | c.2163A>G p.E721= | Silent (SNP) | VAF 49/129 reads (38%) | catalogued as COSV61060239; called by muse, mutect2, varscan2
- GPR157 | c.183C>T p.A61= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV66233742; called by muse, mutect2, varscan2
- GPR87 | c.18G>T p.T6= | Silent (SNP) | VAF 4/84 reads (5%) | catalogued as COSV53463275; called by muse, mutect2
- HS6ST3 | c.759C>T p.S253= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as rs368146960; called by muse, mutect2, varscan2
- KIZ | c.798T>A p.S266= | Silent (SNP) | VAF 38/109 reads (35%) | catalogued as COSV55685398; called by muse, mutect2, varscan2
- LAD1 | c.1431G>A p.L477= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV66212592; called by muse, mutect2, varscan2
- MATN2 | c.2682T>C p.S894= | Silent (SNP) | VAF 48/182 reads (26%) | catalogued as COSV54712204; called by muse, mutect2, varscan2
- MTMR8 | c.1470C>A p.P490= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV66394115; called by muse, mutect2, varscan2
- NOS1 | c.1254G>A p.S418= | Silent (SNP) | VAF 32/118 reads (27%) | catalogued as rs946356254, COSV57608982; called by muse, mutect2, varscan2
- OR5H14 | c.117C>A p.I39= | Silent (SNP) | VAF 184/535 reads (34%) | catalogued as COSV71194002; called by muse, mutect2, varscan2
- PCDHA10 | c.66C>T p.A22= | Silent (SNP) | VAF 49/71 reads (69%) | catalogued as COSV56507038; called by muse, mutect2, varscan2
- PLPPR4 | c.1497T>C p.N499= | Silent (SNP) | VAF 38/96 reads (40%) | catalogued as COSV64566041; called by muse, mutect2, varscan2
- ROBO1 | c.3282T>C p.S1094= | Silent (SNP) | VAF 57/173 reads (33%) | catalogued as COSV71394865; called by muse, mutect2, varscan2
- SLC22A10 | c.486A>T p.I162= | Silent (SNP) | VAF 33/113 reads (29%) | catalogued as COSV60421502; called by muse, mutect2, varscan2
- ZC3HAV1 | c.1305G>T p.V435= | Silent (SNP) | VAF 109/234 reads (47%) | catalogued as COSV54296467; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152445794 C>T | 3'Flank (SNP) | VAF 14/84 reads (17%) | catalogued as rs767525571; called by muse, mutect2, varscan2
- FAM3A | c.152-75G>T | Intron (SNP) | VAF 74/219 reads (34%) | called by muse, mutect2, varscan2
- OLIG2 | c.*778A>C | 3'UTR (SNP) | VAF 37/132 reads (28%) | catalogued as COSV100324185; called by muse, varscan2
- VAMP4 | c.*10A>G | 3'UTR (SNP) | VAF 81/344 reads (24%) | catalogued as COSV99358591; called by muse, mutect2, varscan2
